Somatic mutation profile of tumor specimen TCGA-A2-A0EP-01A (aliquot TCGA-A2-A0EP-01A-52D-A22X-09) from TCGA case TCGA-A2-A0EP, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 56.4 years (20,585 days).
Specimen TCGA-A2-A0EP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56c76b67-01b6-4d92-92e2-b4c8db7feb67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0EP-10A (Blood Derived Normal), aliquot TCGA-A2-A0EP-10A-01D-A22X-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/faad600f-bfb1-416c-b7be-42c7cc337ecc

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD36B | c.1319A>G p.K440R | Missense Mutation (SNP) | VAF 10/322 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99308002; called by muse, mutect2
- ARHGEF11 | c.1231G>C p.E411Q | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100809780; called by muse, mutect2
- GPR161 | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV54793113, COSV99606309; called by muse, mutect2
- IGHV4-28 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.491); catalogued as rs782085195; called by muse, mutect2
- MSRA | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100412498; called by muse, mutect2
- PATE1 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 11/161 reads (7%) | catalogued as COSV59824204; called by muse, mutect2
- ELAVL1 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.69); called by muse, mutect2
- RPS6KA2 | c.144G>A p.K48= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV99690339; called by muse, mutect2
